Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A17K, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A17K-01A (Primary Tumor).

[page 1 of 2]
1CB-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3

12/9/10

Site Code: Endometrium C54.1

lu

Surgical Pathology

DIAGNOSIS:

A. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: FIGO grade II (of III) endometrial adenocarcinoma, endometrioid type, is identified forming a polypoid mass (3.0 x 2.3 x 1.0 cm) involving the polyp. The tumor is confined to the polyp and immediately adjacent endometrium and does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. The bilateral ovaries and fallopian tubes are not involved. [AJCCpT1aNXXM].

This final pathology report is based on the gross/macroscopic examination and frozen section histologic evaluation of the specimen(s).

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, right and left ovaries and fallopian tubes" is a 94.7 gram uterus with attached bilateral tubes and ovaries. The uterine serosa is smooth. There is a 3.0 x 2.3 x 1.0 cm non-invasive mass in the left wall of the endometrial cavity with 1.6 cm myometrial thickness. There are multiple (2) uterine intramural leiomyomas, ranging from 0.2 cm and 0.9 cm in greatest dimension. There is a 2.5 x 1.1 x 1.0 cm right ovary with a smooth outer surface and a cystic and solid cut surface with a 5.5 x 0.5 cm

[page 2 of 2]
right fallopian tube. There is a 2.8 x 2.3 x 1.1 cm left ovary with a smooth outer surface and a cystic and solid cut surface with a 5.2 and 0.4 cm left fallopian tube. Representative sections are submitted.

BLOCK SUMMARY:

Part A: Uterus, tubes, ovaries

- 1 Endometrium tumor base
- 2 Endometrium mass-1
- 3 Endometrium mass-2
- 4 Endomet tumor base-2
- 5 Endometrium
- 6 6:00 cervix
- 7 Myomet
- 8 Rt ovary
- 9 Rt tube
- 10 Lt ovary
- 11 Lt tube
- 12 Endometrium-2

ICDPA Discrepancy		/

Source: NCI Genomic Data Commons file c6185295-47bf-4a9c-a095-682ea93ee09a (TCGA-D1-A17K.C9E1B85A-8637-4421-A8CD-2E4BB28B3A73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).